Somatic mutation profile of tumor specimen C3L-02468-03 (aliquot CPT0126000009) from CPTAC case C3L-02468, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 63.5 years (23,177 days).
Specimen C3L-02468-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7226648c-583e-4b30-bd50-df3d67924f1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02468-31 (Blood Derived Normal), aliquot CPT0124280002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/085b14d6-ef19-41fb-9aaa-631917909021

The open-access MAF lists 207 somatic variants for this specimen: 120 protein-altering or splice-affecting, 49 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 49, Intron 20, Frame Shift Del 7, RNA 7, Nonsense Mutation 4, 3'Flank 3, 5'Flank 3, 5'UTR 3, 3'UTR 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLN8 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs386834124, CM120922; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2
- PTEN | c.801+1G>T p.X267_splice | Splice Site (SNP) | VAF 46/267 reads (17%) | hotspot (GDC flag); catalogued as CD011189, CS002685, CS992481, COSV64296194, COSV64297522; called by muse, mutect2, varscan2
- ABCC3 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53329533; called by muse, mutect2
- ACACB | c.6190G>A p.G2064R | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150701956; called by muse, mutect2
- AKR1E2 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 23/263 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs141566915; called by muse, mutect2
- ALDH4A1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51890561; called by muse, mutect2, varscan2
- ATAD2B | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.657); catalogued as rs1375708519; called by muse, mutect2
- B4GALNT4 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1179565332; called by muse, mutect2, varscan2
- BHLHE22 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 28/703 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV58861252; called by muse, mutect2
- BTNL9 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 36/587 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs927944317; called by muse, mutect2
- C12orf40 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs867271556, COSV100210380; called by muse, mutect2
- CFH | c.2635G>A p.G879R | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245312471, COSV100809944; called by muse, mutect2
- CHRNA10 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 31/404 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as rs2231542, COSV51706007; called by muse, mutect2
- COL12A1 | c.628del p.I210Ffs*9 | Frame Shift Del (DEL) | VAF 16/126 reads (13%) | catalogued as rs757069984; called by mutect2, varscan2
- DNAH1 | c.7420C>T p.R2474C | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228450839, COSV70237162; called by muse, mutect2
- DNAH17 | c.4048G>A p.V1350M | Missense Mutation (SNP) | VAF 48/485 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs373436522; called by muse, mutect2
- ELK3 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1063997; called by muse, mutect2
- GABRA5 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165907; called by muse, mutect2
- GDPD5 | c.1462del p.L488Sfs*48 | Frame Shift Del (DEL) | VAF 16/176 reads (9%) | catalogued as COSV100409095; called by mutect2, pindel
- GLI3 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 48/684 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM127567, COSV101229798; called by muse, mutect2
- HERC2 | c.11116G>A p.V3706I | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs771841707, COSV55348289; called by muse, mutect2
- HIRA | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 21/313 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1264242256, COSV54275885; called by muse, mutect2
- HTR1A | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 28/717 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100109053; called by muse, mutect2
- IGF2R | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs142589883; called by muse, mutect2
- INTS5 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57951423; called by muse, mutect2
- IQCA1 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.586); catalogued as COSV54496917; called by muse, mutect2
- JAG2 | c.2819G>A p.R940Q | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs774068774; called by muse, mutect2
- KLHL33 | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1269493198; called by muse, mutect2
- LEFTY2 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 53/622 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.567); catalogued as rs750344975; called by muse, mutect2
- MACF1 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 29/243 reads (12%) | catalogued as rs373088168; called by muse, mutect2, varscan2
- MYH15 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1281379382; called by muse, mutect2
- MYO5B | c.2630G>A p.R877H | Missense Mutation (SNP) | VAF 28/395 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs745379191, COSV53216011; called by muse, mutect2
- MYOM2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 17/365 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs147661043, COSV50717399; called by muse, mutect2
- NBEAL2 | c.5938C>T p.R1980C | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52757486; called by muse, mutect2
- NEUROG3 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV54342469; called by muse, mutect2
- NRG3 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV64575475; called by muse, mutect2, varscan2
- NTRK2 | c.2192C>T p.T731M (on ENST00000323115 / NM_001369534.1; = p.T747M on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52870633, COSV52876088; called by muse, mutect2
- OCLN | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.228); catalogued as rs747199223; called by muse, mutect2
- PCDHGA11 | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as rs765694240; called by muse, mutect2
- PCDHGA5 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 53/585 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as COSV54003429; called by muse, mutect2
- PCOLCE | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.784); catalogued as rs1357758391; called by muse, mutect2
- PRKDC | c.11654G>A p.R3885Q | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs772389987; called by muse, mutect2
- PRLH | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 48/652 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138895198; called by muse, mutect2
- PTPN1 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 6/106 reads (6%) | catalogued as rs1443524226; called by muse, mutect2
- RHOT2 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 61/848 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs547237251; called by muse, mutect2
- SF1 | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV57115937; called by muse, mutect2
- SHH | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 27/518 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs141313715; called by muse, mutect2
- SIPA1L3 | c.4655G>A p.R1552H | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as rs368732760; called by muse, mutect2
- SMAD2 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs773849578; called by muse, mutect2
- SNX1 | c.1047G>C p.K349N | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252962466; called by muse, mutect2
- SNX14 | c.892_894del p.I298del (on ENST00000314673 / NM_001350535.1; = p.I254del on NM_020468.5 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs1409477442; called by pindel, varscan2
- SYMPK | c.3692C>T p.T1231M | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as rs1236847998, COSV55573567; called by muse, mutect2
- TENM3 | c.7751C>T p.T2584M | Missense Mutation (SNP) | VAF 11/351 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs1281742771; called by muse, mutect2
- TNRC18 | c.1505del p.P502Rfs*88 | Frame Shift Del (DEL) | VAF 49/489 reads (10%) | catalogued as rs759798146; called by mutect2, pindel, varscan2
- TPI1 | c.373G>A p.G125R (on ENST00000229270; = p.G88R on NM_000365.6) | Missense Mutation (SNP) | VAF 24/796 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs911072345, COSV99223024; called by muse, mutect2
- TRIM67 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs372382212, COSV64158042; called by muse, mutect2
- VN1R2 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100448252; called by muse, mutect2
- VPS13B | c.1365G>A p.M455I | Missense Mutation (SNP) | VAF 30/422 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1187769339; called by muse, mutect2
- VWA2 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 21/390 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs759923665, COSV100073989; called by muse, mutect2
- WDR55 | c.1022A>G p.K341R | Missense Mutation (SNP) | VAF 66/626 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs201744244, COSV56905332; called by muse, varscan2
- WFS1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs537004839; called by muse, mutect2
- ZNF563 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 23/344 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs760842286, COSV53369553; called by muse, mutect2
- ZNF781 | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.648); catalogued as COSV62201585; called by muse, mutect2
- ZNRF3 | c.919C>T p.R307W (on ENST00000544604 / NM_001206998.2; = p.R207W on NM_032173.3) | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60431866; called by muse, mutect2
- AASS | c.2708T>A p.I903N | Missense Mutation (SNP) | VAF 14/384 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- ABCB1 | c.3536G>A p.G1179D | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ARFGEF3 | c.5471C>T p.A1824V | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.985); called by muse, mutect2
- C1orf116 | c.1719del p.C574Vfs*20 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel
- CA2 | c.365A>G p.H122R | Missense Mutation (SNP) | VAF 31/466 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CAPRIN1 | c.1660C>T p.H554Y | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); called by muse, mutect2
- CCL3 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 20/500 reads (4%) | called by muse, mutect2
- CDK12 | c.3077G>T p.S1026I | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2
- CGNL1 | c.3267G>T p.E1089D | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2
- CHSY3 | c.2243G>C p.S748T | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRAT | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, varscan2
- CRB1 | c.2099G>A p.R700K | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CRYGB | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DND1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 27/337 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2
- DYNC1H1 | c.3629A>G p.Y1210C | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2
- ECM1 | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2
- GFRAL | c.571T>A p.C191S | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HK2 | c.1889G>A p.G630D | Missense Mutation (SNP) | VAF 56/679 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- HOXD9 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2
- ICE1 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ITGA1 | c.3201del p.F1067Lfs*28 | Frame Shift Del (DEL) | VAF 17/166 reads (10%) | called by mutect2, pindel, varscan2
- KIF23 | c.1186C>A p.L396M | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- LRFN4 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAGEA6 | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 28/612 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MLNR | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- MMP23B | c.870C>T p.Y290= | Splice Region (SNP) | VAF 15/81 reads (19%) | called by mutect2, varscan2
- MTCH1 | c.949A>C p.M317L (on ENST00000373627 / NM_001271641.1; = p.M300L on NM_014341.2) | Missense Mutation (SNP) | VAF 29/437 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); called by muse, mutect2
- NR4A2 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- NSUN4 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PANK4 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDCD10 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 11/354 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.866); called by muse, mutect2
- POMT2 | c.1105C>A p.R369S | Missense Mutation (SNP) | VAF 28/399 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2
- PPP2R5A | c.376del p.M126* | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- PRSS12 | c.2353G>A p.A785T | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.15); called by muse, mutect2
- PXN | c.1007G>A p.S336N (on ENST00000228307 / NM_001080855.3; = p.S302N on NM_002859.4) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAPH1 | c.518A>G p.Q173R | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- RPS24 | c.446_447del p.R149Mfs*51 | Frame Shift Del (DEL) | VAF 12/108 reads (11%) | called by pindel, varscan2
- RSPO1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- SCNN1A | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.95); called by muse, mutect2
- SHROOM2 | c.1952C>T p.T651I | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.146); called by muse, mutect2
- SKI | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC34A1 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPECC1 | c.2833C>G p.L945V | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2
- SPTBN5 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 18/326 reads (6%) | called by muse, mutect2
- SRSF3 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.135); called by muse, mutect2
- STAT5A | c.65A>T p.Y22F | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- TAF1L | c.5365A>G p.I1789V | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.232); called by muse, mutect2
- TES | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 35/663 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TGFBR3 | c.2479G>A p.A827T | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.299); called by muse, mutect2
- TMEM183A | c.1112C>A p.P371Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNS4 | c.1779G>T p.E593D | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2
- UNC45A | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- URGCP | c.376A>G p.N126D (on ENST00000453200 / NM_001077663.3; = p.N117D on NM_017920.4) | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2
- ZBTB38 | c.2676C>A p.C892* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- ZC3H12A | c.86A>G p.Q29R | Missense Mutation (SNP) | VAF 21/316 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- ZNF266 | c.993A>T p.K331N | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ADRA2A | c.417G>A p.L139= | Silent (SNP) | VAF 30/348 reads (9%) | called by muse, mutect2
- AL645922.1 | c.1080C>T p.N360= | Silent (SNP) | VAF 21/807 reads (3%) | catalogued as rs368351699; called by muse, mutect2
- AMBRA1 | c.1101G>A p.R367= (on ENST00000458649 / NM_001367468.1; = p.R277= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 24/386 reads (6%) | catalogued as COSV54054707; called by muse, mutect2
- ANKRD9 | c.213G>A p.S71= | Silent (SNP) | VAF 21/300 reads (7%) | catalogued as rs1285965028; called by muse, mutect2
- ATP8B4 | c.2886A>T p.G962= | Silent (SNP) | VAF 16/290 reads (6%) | called by muse, mutect2
- B4GALT2 | c.690C>T p.C230= | Silent (SNP) | VAF 22/270 reads (8%) | catalogued as rs546242976, COSV100530534; called by muse, mutect2
- C1orf94 | c.126C>T p.C42= | Silent (SNP) | VAF 24/308 reads (8%) | catalogued as rs921025180; called by muse, mutect2
- COBL | c.2121G>A p.T707= | Silent (SNP) | VAF 18/303 reads (6%) | catalogued as rs143532398; called by muse, mutect2
- CTNND2 | c.1821A>G p.E607= | Silent (SNP) | VAF 24/426 reads (6%) | called by muse, mutect2
- EGR4 | c.1533A>G p.K511= (on ENST00000545030; = p.K408= on NM_001965.4) | Silent (SNP) | VAF 32/532 reads (6%) | called by muse, mutect2
- EHBP1L1 | c.3705G>A p.P1235= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2, varscan2
- EPHB3 | c.1344A>G p.T448= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- FAM120C | c.207C>A p.P69= | Silent (SNP) | VAF 33/474 reads (7%) | called by muse, mutect2
- FAM83D | c.1302G>A p.T434= | Silent (SNP) | VAF 14/191 reads (7%) | catalogued as rs758455015, COSV54156698; called by muse, mutect2
- FOXO4 | c.42G>A p.A14= | Silent (SNP) | VAF 11/338 reads (3%) | called by muse, mutect2
- GABRG2 | c.1095G>A p.S365= (on ENST00000361925 / NM_001375343.1; = p.S325= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/538 reads (5%) | catalogued as rs774809218; ClinVar: likely benign; called by muse, mutect2
- GAL3ST3 | c.1161C>T p.P387= | Silent (SNP) | VAF 11/328 reads (3%) | called by muse, mutect2
- HIPK3 | c.1863G>A p.Q621= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV100305625; called by muse, mutect2
- HR | c.2103C>T p.P701= | Silent (SNP) | VAF 15/164 reads (9%) | catalogued as rs777959884, COSV57193029; called by muse, mutect2
- IL4I1 | c.1458G>A p.P486= | Silent (SNP) | VAF 17/175 reads (10%) | called by muse, mutect2
- ITSN2 | c.2301C>A p.P767= | Silent (SNP) | VAF 12/184 reads (7%) | catalogued as COSV100743966; called by muse, mutect2
- KIRREL2 | c.843C>T p.D281= | Silent (SNP) | VAF 19/398 reads (5%) | catalogued as rs1487303105, COSV52875596; called by muse, mutect2
- LILRB2 | c.390C>A p.P130= | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- LMBRD2 | c.1668C>T p.L556= | Silent (SNP) | VAF 20/387 reads (5%) | catalogued as rs761270217; called by muse, mutect2
- LRP8 | c.735C>T p.C245= | Silent (SNP) | VAF 22/280 reads (8%) | catalogued as rs1271157148; called by muse, mutect2
- MEFV | c.1953C>T p.G651= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- MNT | c.966C>A p.P322= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as rs765856528; called by muse, mutect2
- NDOR1 | c.711C>T p.G237= | Silent (SNP) | VAF 9/207 reads (4%) | called by muse, mutect2
- NEURL4 | c.2413C>T p.L805= | Silent (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2
- NGFR | c.393C>T p.G131= | Silent (SNP) | VAF 26/418 reads (6%) | called by muse, mutect2
- NT5DC2 | c.1197G>A p.T399= | Silent (SNP) | VAF 19/309 reads (6%) | catalogued as rs755943743; called by muse, mutect2
- NUP62 | c.561G>A p.T187= | Silent (SNP) | VAF 32/319 reads (10%) | catalogued as rs149405354, COSV61312229; called by muse, mutect2, varscan2
- OTUD7A | c.2655C>T p.C885= (on ENST00000307050 / NM_001382637.1; = p.C878= on NM_130901.3) | Silent (SNP) | VAF 27/304 reads (9%) | catalogued as rs1402024732; called by muse, mutect2
- PDGFRA | c.1434C>A p.S478= | Silent (SNP) | VAF 13/341 reads (4%) | called by muse, mutect2
- PHRF1 | c.1365C>A p.S455= (on ENST00000264555 / NM_001286581.2; = p.S454= on NM_020901.4) | Silent (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- PXDNL | c.2601C>T p.P867= | Silent (SNP) | VAF 16/275 reads (6%) | catalogued as COSV62482797, COSV62486935; called by muse, mutect2
- RARA | c.669C>T p.D223= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- RBM24 | c.510T>C p.A170= (on ENST00000379052 / NM_001143942.2; = p.A125= on NM_153020.2) | Silent (SNP) | VAF 16/231 reads (7%) | catalogued as rs747765701, COSV59002688; called by muse, mutect2
- RHOBTB2 | c.921C>G p.G307= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- RPS19BP1 | c.34C>T p.L12= | Silent (SNP) | VAF 26/297 reads (9%) | catalogued as rs59991531; called by muse, mutect2
- SEMA6A | c.2526G>A p.A842= | Silent (SNP) | VAF 38/681 reads (6%) | catalogued as rs372919590; called by muse, mutect2
- SIRT2 | c.735C>A p.S245= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- STX5 | c.765G>A p.Q255= | Silent (SNP) | VAF 19/374 reads (5%) | called by muse, mutect2
- TEX11 | c.2817A>G p.S939= (on ENST00000344304; = p.S924= on NM_031276.3) | Silent (SNP) | VAF 15/188 reads (8%) | called by muse, mutect2
- TGM7 | c.141C>T p.F47= | Silent (SNP) | VAF 12/165 reads (7%) | called by muse, mutect2
- TK1 | c.507G>A p.E169= | Silent (SNP) | VAF 27/225 reads (12%) | catalogued as rs746775840, COSV56746526; called by muse, mutect2, varscan2
- TNPO3 | c.1554T>C p.A518= | Silent (SNP) | VAF 24/226 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.98061C>T p.D32687= (on ENST00000591111; = p.D25263= on NM_003319.4) | Silent (SNP) | VAF 21/357 reads (6%) | catalogued as rs541125667, COSV59988084; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance / benign; called by muse, mutect2
- ZC3H4 | c.2484G>A p.T828= | Silent (SNP) | VAF 33/261 reads (13%) | catalogued as rs746387202; called by muse, mutect2, varscan2
- ABI3BP | c.1577-9206C>T | Intron (SNP) | VAF 5/51 reads (10%) | catalogued as rs1165019836; called by muse, mutect2, varscan2
- AC007952.2 | chr17:19093696 C>T | 5'Flank (SNP) | VAF 87/557 reads (16%) | catalogued as rs1377123716; called by muse, mutect2, varscan2
- AC135782.1 | n.304G>A | RNA (SNP) | VAF 30/328 reads (9%) | called by muse, mutect2
- ADAM17 | c.843+838C>A | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- ADAM6 | n.1437C>T | RNA (SNP) | VAF 17/250 reads (7%) | catalogued as rs140841048; called by muse, mutect2
- ARMCX4 | c.1038+222G>A | Intron (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- BET1L | c.-5G>A | 5'UTR (SNP) | VAF 12/339 reads (4%) | called by muse, mutect2
- C10orf105 | c.-58G>A | 5'UTR (SNP) | VAF 18/529 reads (3%) | called by muse, mutect2
- CARD6 | chr5:40860036 G>A | 3'Flank (SNP) | VAF 8/179 reads (4%) | catalogued as rs1210617601; called by muse, mutect2
- CCDC105 | chr19:15010485 C>T | 5'Flank (SNP) | VAF 10/179 reads (6%) | catalogued as rs1040869908; called by muse, mutect2
- CENPJ | c.3302-711A>G | Intron (SNP) | VAF 23/375 reads (6%) | called by muse, mutect2
- CHRNB1 | c.244-45C>A | Intron (SNP) | VAF 21/236 reads (9%) | called by muse, mutect2
- EPCAM | c.184+29G>T | Intron (SNP) | VAF 11/189 reads (6%) | called by muse, mutect2
- FAAP20 | c.471-694G>A | Intron (SNP) | VAF 9/82 reads (11%) | catalogued as rs1306298400; called by muse, mutect2, varscan2
- FBL | c.942-36G>A | Intron (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- HLA-V | n.273C>T | RNA (SNP) | VAF 11/241 reads (5%) | called by muse, mutect2
- ING5 | c.483-3447C>T | Intron (SNP) | VAF 14/200 reads (7%) | catalogued as rs1006891844; called by muse, mutect2
- LINC00479 | n.430+121C>A | Intron (SNP) | VAF 6/143 reads (4%) | called by muse, mutect2
- LINC01561 | n.564G>T | RNA (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2
- MIB1 | c.1829+6102G>A | Intron (SNP) | VAF 28/310 reads (9%) | catalogued as rs574177540, COSV99838296; called by muse, mutect2
- MOB2 | chr11:1469984 G>A | 3'Flank (SNP) | VAF 14/387 reads (4%) | catalogued as rs1006323215; called by muse, mutect2
- MYO1G | chr7:44984012 G>T | 5'Flank (SNP) | VAF 44/582 reads (8%) | called by muse, mutect2
- NEK8 | c.487-31C>T | Intron (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- NHP2 | c.230+21G>A | Intron (SNP) | VAF 18/366 reads (5%) | called by muse, mutect2
- NUDT16L1 | c.-25C>T | 5'UTR (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- PDXK | c.88-1686T>G | Intron (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- PIPSL | n.2016C>T | RNA (SNP) | VAF 29/310 reads (9%) | catalogued as rs953829331; called by muse, mutect2
- PRDM11 | chr11:45227990 C>T | 3'Flank (SNP) | VAF 34/250 reads (14%) | catalogued as rs1209260999; called by muse, mutect2, varscan2
- RAB18 | c.*3641del | 3'UTR (DEL) | VAF 14/124 reads (11%) | catalogued as rs771049979; called by mutect2, varscan2
- SCRIB | c.4178-15C>A | Intron (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- SLC3A2 | c.994-444del | Intron (DEL) | VAF 19/179 reads (11%) | called by mutect2, pindel
- SPATA13 | c.-222-26580C>T | Intron (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- SPINK5 | c.475-245G>T | Intron (SNP) | VAF 18/260 reads (7%) | called by muse, mutect2
- SSPOP | n.9793del | RNA (DEL) | VAF 24/251 reads (10%) | catalogued as rs770564198, COSV100947664; called by mutect2, pindel, varscan2
- TM7SF2 | c.1097-92C>T | Intron (SNP) | VAF 27/336 reads (8%) | catalogued as rs1395408116; called by muse, mutect2
- TMEM183B | n.693A>G | RNA (SNP) | VAF 45/552 reads (8%) | called by muse, mutect2
- TRIM36 | c.64-5884C>T | Intron (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
- ZNF99 | c.*1002A>T | 3'UTR (SNP) | VAF 34/286 reads (12%) | called by muse, mutect2, varscan2
